Surgical pathology report (de-identified scan), TCGA case TCGA-28-2514, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-2514-01A (Primary Tumor).

TCGA - 28 - 2514

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A, G. LEFT TEMPORAL TUMOR (CRANIOTOMY FOR RESECTION):

- Glioblastoma multiforme (WHO grade IV)

B. LEFT TEMPORAL TUMOR, NCI PROTOCOL:

- Cellular tumor without necrosis

C. LEFT TEMPORAL TUMOR, NCI PROTOCOL:

- Cellular tumor without necrosis

D. LEFT TEMPORAL TUMOR, NCI PROTOCOL:

- Cellular tumor with approximately 15% tumor necrosis (5% in one core and 10% in another core)

E. LEFT TEMPORAL TUMOR, NCI PROTOCOL:

- Cellular tumor with approximately 10% necrosis (5% in each core)

F. LEFT TEMPORAL TUMOR, NCI PROTOCOL:

- Cellular tumor with approximately 5% tumor necrosis in one core

COMMENT: Immunostain for MGMT is considered to be negative (less than 5% tumor cell positive). Immunostain for PTEN and MAPK are positive. There is a marked elevation of laminin beta-1 and laminin beta-2 (see Note).

NOTE:

A low percentage of tumor cells (20% and less) immunostaining for MGMT has been reported to be associated with a relative response to Temodar. Hence, the less than 5% result in this case may suggest a likelihood of being responsive to Temodar.

Presence of activated (phosphorylated) p42/44 mitogen-activated protein kinase (pMAPK) in glioblastoma multiforme has been shown to be associated with a relative resistance to radiation therapy. Hence, a high percentage of tumor cells immunoreactive to pMAPK antibody (although a cut-off point has not been well established yet at the moment) in this case may suggest the possibility of a relative resistance to radiation therapy.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas. Hence, retained expression of PTEN in this case may suggest the possibility of a relatively favorable prognosis.

Recent studies have shown an adverse prognostic significance of increased laminin $\beta 1$ and increased laminin $\beta 2$ (laminin-9) expression predicting a worse survival of patients with high grade gliomas. Association between laminin-8 and glial tumor grade, recurrence, and patient survival. Elevated expression of laminin $\beta 1$ and $\beta 2$ in this tumor may suggest the tumor aggressiveness intermediate between the $\downarrow\beta 1$ (or normal)/ $\uparrow\beta 2$ (or normal) (the most favorable prognosis) and $\uparrow\beta 1/\downarrow\beta 2$ (the least favorable prognosis).

However, the use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

Source: NCI Genomic Data Commons file 25df11c1-2187-4bf4-a599-f8ec54fd2d99 (TCGA-28-2514.D2CBB615-C4B7-4AE0-9DE7-B31241302CE7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).